Somatic mutation profile of tumor specimen TCGA-BP-5192-01A (aliquot TCGA-BP-5192-01A-01D-1429-08) from TCGA case TCGA-BP-5192, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 59.9 years (21,891 days).
Specimen TCGA-BP-5192-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 981cc9d9-cbb7-4785-8e09-e4c615cdedd5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BP-5192-11A (Solid Tissue Normal), aliquot TCGA-BP-5192-11A-01D-1429-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ca8d9f1c-a098-476a-b5ef-f63e40e3b571

The open-access MAF lists 55 somatic variants for this specimen: 43 protein-altering or splice-affecting, 12 silent.
By variant classification: Missense Mutation 30, Silent 12, Frame Shift Del 7, In Frame Del 3, Nonsense Mutation 1, Splice Site 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC090517.4 | c.166T>C p.Y56H | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.044); catalogued as rs1267743157, COSV50997812; called by muse, mutect2, varscan2
- AC109583.1 | c.762G>A p.W254* | Nonsense Mutation (SNP) | VAF 47/241 reads (20%) | catalogued as COSV58405957; called by muse, mutect2, varscan2
- ANK3 | c.9845T>C p.I3282T | Missense Mutation (SNP) | VAF 144/409 reads (35%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as rs749603197, COSV55043640, COSV55063154; called by muse, mutect2, varscan2
- ANKRD17 | c.2362T>A p.L788M | Missense Mutation (SNP) | VAF 58/179 reads (32%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.007); catalogued as COSV58222435; called by muse, mutect2, varscan2
- ARHGAP45 | c.515A>G p.N172S | Missense Mutation (SNP) | VAF 34/152 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.702); catalogued as COSV57433094; called by muse, mutect2, varscan2
- ASB16 | c.443A>G p.H148R | Missense Mutation (SNP) | VAF 46/150 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs865901269, COSV53235216; called by muse, mutect2, varscan2
- BICD2 | c.284A>T p.D95V | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV63549426; called by muse, mutect2, varscan2
- BRPF1 | c.3591G>T p.Q1197H | Missense Mutation (SNP) | VAF 7/163 reads (4%) | SIFT tolerated (0.59); PolyPhen benign (0.329); catalogued as COSV57353523; called by muse, mutect2
- CAMSAP1 | c.2695A>C p.M899L | Missense Mutation (SNP) | VAF 44/178 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as COSV56723888; called by muse, mutect2, varscan2
- CDC25C | c.278T>A p.L93H | Missense Mutation (SNP) | VAF 241/488 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as COSV60399884; called by muse, mutect2, varscan2
- COL4A5 | c.2266C>T p.P756S | Missense Mutation (SNP) | VAF 103/138 reads (75%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV60363981; called by muse, mutect2, varscan2
- CSMD1 | c.941C>T p.A314V | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.919); catalogued as rs752440260, COSV68173715, COSV68217391; called by muse, mutect2, varscan2
- DNAAF1 | c.2177A>G p.*726Wext*? | Nonstop Mutation (SNP) | VAF 72/192 reads (38%) | catalogued as COSV58987190; called by muse, mutect2, varscan2
- DNAJB11 | c.467A>C p.N156T | Missense Mutation (SNP) | VAF 60/169 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV54002890; called by muse, mutect2, varscan2
- FAT4 | c.13526C>T p.A4509V | Missense Mutation (SNP) | VAF 52/142 reads (37%) | SIFT tolerated, low confidence (0.2); PolyPhen probably damaging (0.987); catalogued as COSV58690927; called by muse, mutect2, varscan2
- KCNB2 | c.553A>G p.K185E | Missense Mutation (SNP) | VAF 61/213 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as COSV73050891; called by muse, mutect2, varscan2
- KCND3 | c.1690G>A p.A564T | Missense Mutation (SNP) | VAF 55/150 reads (37%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.021); catalogued as rs1486298373, CM131388, COSV56182712; called by muse, mutect2, varscan2
- KIF17 | c.2650T>C p.S884P | Missense Mutation (SNP) | VAF 58/156 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); catalogued as COSV56119229; called by muse, mutect2, varscan2
- LRRC24 | c.838G>C p.A280P | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.892); catalogued as COSV52880127; called by muse, mutect2
- MAGT1 | c.845G>C p.G282A (on ENST00000618282 / NM_001367916.1; = p.G314A on NM_032121.5) | Missense Mutation (SNP) | VAF 106/143 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV63234240; called by muse, mutect2, varscan2
- MRPL14 | c.251C>T p.A84V | Missense Mutation (SNP) | VAF 176/519 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as rs368426589; called by muse, mutect2, varscan2
- MSLNL | c.1086+1G>A p.X362_splice | Splice Site (SNP) | VAF 8/92 reads (9%) | catalogued as COSV53503324; called by muse, mutect2
- NSD3 | c.3543del p.E1182Kfs*15 | Frame Shift Del (DEL) | VAF 21/86 reads (24%) | catalogued as COSV57668208; called by mutect2, pindel, varscan2
- PCDHA12 | c.8T>A p.I3N | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.072); catalogued as COSV56514013; called by muse, varscan2
- PHACTR1 | c.1582G>C p.V528L | Missense Mutation (SNP) | VAF 66/192 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as COSV60670226; called by muse, mutect2, varscan2
- PLEKHA6 | c.406T>G p.Y136D | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55335329; called by muse, mutect2, varscan2
- PPARGC1B | c.2282G>A p.R761H | Missense Mutation (SNP) | VAF 110/389 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs755486310, COSV58530310; called by muse, mutect2, varscan2
- PSD2 | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 36/160 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51202316; called by muse, mutect2, varscan2
- PTPRJ | c.1448A>G p.Q483R | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV69252820; called by muse, mutect2, varscan2
- RACGAP1 | c.1882T>C p.S628P | Missense Mutation (SNP) | VAF 43/149 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as COSV56699620; called by muse, mutect2, varscan2
- RFC1 | c.1922G>T p.G641V (on ENST00000381897 / NM_001363496.2; = p.G640V on NM_002913.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs374867437; called by muse, mutect2, varscan2
- RFC1 | c.1921G>T p.G641C (on ENST00000381897 / NM_001363496.2; = p.G640C on NM_002913.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV62900004; called by muse, mutect2, varscan2
- RUNX3 | c.172G>C p.V58L | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.046); catalogued as rs761109803, COSV58244542, COSV58244778; called by muse, varscan2
- TMEM81 | c.433G>T p.V145L | Missense Mutation (SNP) | VAF 59/198 reads (30%) | SIFT tolerated (0.55); PolyPhen benign (0.006); catalogued as COSV52705201; called by muse, mutect2, varscan2
- COL17A1 | c.1544_1549del p.S515_D517delinsN | In Frame Del (DEL) | VAF 71/265 reads (27%) | called by mutect2, pindel, varscan2
- HLA-DRA | c.344_345del p.T115Sfs*68 | Frame Shift Del (DEL) | VAF 40/90 reads (44%) | called by mutect2, pindel, varscan2
- KDR | c.866del p.L289* | Frame Shift Del (DEL) | VAF 63/198 reads (32%) | called by mutect2, pindel, varscan2
- KLC1 | c.264del p.M89* | Frame Shift Del (DEL) | VAF 32/99 reads (32%) | called by mutect2, pindel, varscan2
- LZTR1 | c.1696del p.C566Afs*26 | Frame Shift Del (DEL) | VAF 15/49 reads (31%) | called by mutect2, pindel, varscan2
- NPR2 | c.2884_2886del p.T962del | In Frame Del (DEL) | VAF 50/158 reads (32%) | called by mutect2, pindel, varscan2
- SMG8 | c.2797_2808del p.P933_V936del | In Frame Del (DEL) | VAF 42/158 reads (27%) | called by mutect2, pindel, varscan2
- TNS2 | c.2101_2110del p.T701Cfs*52 (on ENST00000314250 / NM_170754.4; = p.T711Cfs*52 on NM_015319.2) | Frame Shift Del (DEL) | VAF 26/103 reads (25%) | called by mutect2, pindel, varscan2
- VHL | c.501_504del p.S168* | Frame Shift Del (DEL) | VAF 19/48 reads (40%) | called by mutect2, pindel, varscan2
- DDB1 | c.3039A>G p.V1013= | Silent (SNP) | VAF 114/333 reads (34%) | catalogued as rs1398847679, COSV57103654; called by muse, mutect2, varscan2
- DUSP19 | c.639G>A p.Q213= | Silent (SNP) | VAF 46/135 reads (34%) | catalogued as COSV61193407; called by muse, mutect2, varscan2
- GPR26 | c.423G>A p.A141= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as COSV52934512; called by muse, mutect2, varscan2
- KCNK10 | c.597G>A p.L199= | Silent (SNP) | VAF 11/312 reads (4%) | catalogued as COSV100069045, COSV56646944; called by muse, mutect2
- KIF17 | c.2649G>A p.E883= | Silent (SNP) | VAF 57/155 reads (37%) | catalogued as COSV56119248; called by muse, mutect2, varscan2
- MYOM1 | c.4038A>G p.E1346= | Silent (SNP) | VAF 38/75 reads (51%) | catalogued as COSV55293858; called by muse, mutect2, varscan2
- R3HDM1 | c.1485C>T p.F495= | Silent (SNP) | VAF 66/204 reads (32%) | catalogued as COSV51526256; called by muse, mutect2, varscan2
- SHROOM4 | c.4185C>T p.S1395= | Silent (SNP) | VAF 30/46 reads (65%) | catalogued as COSV56791131; called by muse, mutect2, varscan2
- SPHKAP | c.2283T>C p.A761= | Silent (SNP) | VAF 131/354 reads (37%) | catalogued as COSV60883035; called by muse, mutect2, varscan2
- STXBP1 | c.54G>T p.V18= | Silent (SNP) | VAF 27/66 reads (41%) | catalogued as COSV64813622; called by muse, mutect2, varscan2
- TECTB | c.429G>A p.V143= | Silent (SNP) | VAF 43/150 reads (29%) | catalogued as COSV65595625; called by muse, mutect2, varscan2
- TMPRSS9 | c.2085C>T p.L695= (on ENST00000648592; = p.L661= on NM_182973.2) | Silent (SNP) | VAF 153/425 reads (36%) | catalogued as COSV60228600; called by muse, mutect2, varscan2
